Somatic mutation profile of tumor specimen TCGA-NC-A5HI-01A (aliquot TCGA-NC-A5HI-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HI, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.4 years (24,981 days).
Specimen TCGA-NC-A5HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bb33cea-1e79-4dd0-912f-5360ffe6593c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HI-10A (Blood Derived Normal), aliquot TCGA-NC-A5HI-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cd36182-a24b-4c88-98c1-9803de6d1fba

The open-access MAF lists 479 somatic variants for this specimen: 367 protein-altering or splice-affecting, 101 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 101, Nonsense Mutation 29, Frame Shift Del 9, Splice Region 9, Splice Site 9, Frame Shift Ins 7, RNA 3, Intron 3, 3'Flank 2, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AADAT | c.369G>C p.K123N | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100528695; called by muse, mutect2, varscan2
- AAK1 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101276028; called by muse, mutect2
- AC091959.1 | c.3073G>T p.A1025S | Missense Mutation (SNP) | VAF 35/104 reads (34%) | catalogued as rs977319468, COSV100047038, COSV100047220; called by muse, mutect2, varscan2
- ACACB | c.3578G>T p.G1193V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100623200; called by muse, mutect2, varscan2
- ADAM18 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99695999; called by muse, mutect2
- ADCY8 | c.1841G>A p.S614N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as COSV99653774; called by muse, mutect2, varscan2
- ADGRL3 | c.1541C>A p.T514N (on ENST00000506720 / NM_001322402.2; = p.T446N on NM_015236.6) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV101547351; called by muse, mutect2, varscan2
- AEBP2 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as COSV99857972; called by muse, mutect2
- AFDN | c.3920A>G p.N1307S | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); catalogued as COSV100653394; called by muse, mutect2, varscan2
- AKAP7 | c.960G>T p.Q320H (on ENST00000431975 / NM_016377.4; = p.Q53H on NM_004842.4) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99541739; called by muse, mutect2, varscan2
- ALPK1 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV51592770, COSV99454970; called by muse, mutect2, varscan2
- ALPP | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101235183; called by muse, mutect2, varscan2
- ANK1 | c.2295G>T p.S765= | Splice Region (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99226503; called by muse, mutect2, varscan2
- ANKRD24 | c.3156G>C p.K1052N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99518037; called by muse, mutect2, varscan2
- ANKRD9 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99743656; called by muse, mutect2
- APC2 | c.3925G>A p.G1309R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs765487016, COSV99279766; called by muse, varscan2
- ARFGEF2 | c.2534-1G>C p.X845_splice | Splice Site (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100904424; called by muse, mutect2, varscan2
- ARHGAP17 | c.1615G>A p.G539S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.511); catalogued as rs1341105791, COSV99253916; called by muse, mutect2, varscan2
- ARHGAP25 | c.62-1G>C p.X21_splice (on ENST00000409202 / NM_001007231.3; = p.A14P on NM_014882.3) | Splice Site (SNP) | VAF 150/495 reads (30%) | catalogued as COSV99771967; called by muse, mutect2, varscan2
- ARHGAP5 | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100565644; called by muse, mutect2, varscan2
- ARHGEF40 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV100070626; called by muse, mutect2, varscan2
- ARHGEF5 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99283122; called by mutect2, varscan2
- ARID1B | c.5664T>G p.S1888R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV99271292; called by muse, mutect2, varscan2
- ATF7IP | c.3094A>G p.T1032A | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.987); catalogued as COSV99662028; called by muse, mutect2, varscan2
- ATP10D | c.1268T>G p.L423R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99906067; called by muse, mutect2, varscan2
- ATP13A5 | c.1996A>C p.K666Q | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV100665589; called by muse, mutect2
- BAG6 | c.2825G>T p.R942L (on ENST00000676571; = p.R895L on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs747689534, COSV99277498; called by muse, mutect2, varscan2
- BAHD1 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV101346788; called by muse, mutect2, varscan2
- BRCA2 | c.3667C>T p.H1223Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as rs786203756, COSV101204581, COSV66452160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1QA | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV101009526; called by muse, mutect2, varscan2
- C4BPB | c.232+1G>T p.X78_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99700140; called by muse, mutect2, varscan2
- C7 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100496422; called by muse, mutect2, varscan2
- CACNA1E | c.6848A>G p.Y2283C (on ENST00000367573 / NM_001205293.3; = p.Y2240C on NM_000721.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.846); catalogued as COSV100704651; called by muse, mutect2, varscan2
- CACNA1S | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV100755279; called by muse, mutect2, varscan2
- CALML5 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.582); catalogued as rs767115673, COSV100981234; called by muse, mutect2, varscan2
- CAPN7 | c.438-1G>C p.X146_splice | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99512984; called by muse, mutect2, varscan2
- CARD6 | c.1388G>T p.C463F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99621172; called by muse, mutect2, varscan2
- CBX2 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs139509934; called by muse, mutect2, varscan2
- CBX5 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV99267819; called by muse, mutect2, varscan2
- CCDC68 | c.501G>C p.L167F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV100491968, COSV61604896; called by muse, mutect2, varscan2
- CCDC69 | c.714G>T p.R238S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100815214; called by muse, mutect2, varscan2
- CCDC7 | c.3442G>A p.D1148N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV100179119; called by muse, mutect2, varscan2
- CCN6 | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100037168; called by muse, mutect2, varscan2
- CDH19 | c.1931A>G p.E644G | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV100052078; called by muse, mutect2
- CDH19 | c.917T>C p.I306T | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.557); catalogued as COSV100052081; called by muse, mutect2, varscan2
- CDH19 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs759627014, COSV100051553, COSV50972116; called by muse, mutect2, varscan2
- CEACAM20 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100387005, COSV57603510; called by muse, mutect2
- CEACAM7 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99137333; called by muse, mutect2, varscan2
- CENPE | c.2152T>A p.L718M | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs922695430, COSV99478843; called by muse, mutect2, varscan2
- CENPH | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99295618; called by muse, mutect2, varscan2
- CEP112 | c.2692G>T p.E898* (on ENST00000392769 / NM_001353127.1; = p.E154* on NM_001037325.3) | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100439412; called by muse, mutect2, varscan2
- CGN | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs768998187, COSV99642702; called by muse, mutect2, varscan2
- CHD1L | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100787557; called by muse, mutect2, varscan2
- CHD6 | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100498584, COSV58553702; called by muse, mutect2, varscan2
- CHEK1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99629847; called by muse, mutect2, varscan2
- CHIA | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100588806; called by muse, mutect2, varscan2
- CHORDC1 | c.848G>T p.W283L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV100272079; called by muse, mutect2
- CHRM5 | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.837); catalogued as COSV101272027; called by muse, mutect2, varscan2
- CLSPN | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV99231386; called by muse, mutect2, varscan2
- CNOT8 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); catalogued as rs770097487, COSV99597250; called by muse, mutect2, varscan2
- CNTNAP2 | c.1349-1G>T p.X450_splice | Splice Site (SNP) | VAF 58/101 reads (57%) | catalogued as COSV100670198; called by muse, mutect2, varscan2
- CNTNAP5 | c.1823C>A p.S608* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | catalogued as COSV101443964; called by muse, mutect2, varscan2
- COL14A1 | c.2555C>A p.P852Q | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV52848142, COSV99920328; called by muse, mutect2, varscan2
- COL4A4 | c.3883G>T p.G1295C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307521; called by muse, mutect2, varscan2
- COLEC12 | c.573T>A p.N191K | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV101232142; called by muse, mutect2, varscan2
- CPEB4 | c.1546+1G>C p.X516_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99437535; called by muse, mutect2, varscan2
- CR1 | c.5426G>A p.R1809K | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.737); catalogued as rs777865155, COSV100887972; called by muse, varscan2
- CR1 | c.5452G>C p.E1818Q | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.924); catalogued as COSV100887973; called by muse, varscan2
- CRB1 | c.312del p.T105Qfs*43 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV100958243; called by mutect2, pindel, varscan2
- CROT | c.1295A>C p.H432P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755315658, COSV100519644; called by muse, mutect2, varscan2
- CSMD3 | c.6290T>C p.V2097A (on ENST00000297405 / NM_001363185.1; = p.V1993A on NM_052900.3) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV52181237, COSV99844343; called by muse, mutect2, varscan2
- CUBN | c.9656A>T p.Y3219F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100913365; called by muse, mutect2, varscan2
- CUBN | c.8164C>A p.P2722T | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100913367; called by muse, mutect2, varscan2
- CUL9 | c.2802A>T p.A934= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99335889; called by muse, mutect2, varscan2
- D2HGDH | c.508G>C p.A170P | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV100344855; called by muse, mutect2, varscan2
- DACH2 | c.1636G>C p.A546P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100913751; called by muse, mutect2, varscan2
- DAOA | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.133); catalogued as COSV100298869; called by muse, mutect2
- DAPK1 | c.2377A>T p.T793S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100802602; called by muse, mutect2, varscan2
- DCAF8 | c.1739C>G p.S580* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100470729; called by muse, mutect2, varscan2
- DDX60L | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV99488197; called by mutect2, varscan2
- DHX34 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV60895095; called by muse, varscan2
- DHX8 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV52253345, COSV99292550; called by muse, mutect2, varscan2
- DLG1 | c.1938-1G>C p.X646_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100015842; called by muse, mutect2
- DMGDH | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99669409; called by muse, mutect2, varscan2
- DPP10 | c.809C>A p.T270N | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100070558; called by muse, mutect2, varscan2
- DSG3 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV99934607; called by muse, mutect2, varscan2
- DUOXA1 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99973453; called by muse, mutect2, varscan2
- EFCAB6 | c.2337C>A p.D779E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV99414172; called by muse, mutect2, varscan2
- EFNB2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99808916; called by muse, mutect2, varscan2
- EIF3H | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99412206; called by muse, mutect2, varscan2
- ELF5 | c.589G>T p.D197Y (on ENST00000312319 / NM_198381.2; = p.D187Y on NM_001422.4) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99141256; called by muse, mutect2, varscan2
- ELOVL7 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV101415635; called by muse, mutect2, varscan2
- ENTPD3 | c.950A>C p.Y317S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100088981; called by muse, mutect2, varscan2
- ENTPD6 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737152; called by muse, mutect2, varscan2
- EPM2AIP1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); catalogued as COSV99212627; called by muse, mutect2, varscan2
- ERC1 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 33/143 reads (23%) | catalogued as COSV100706592; called by muse, mutect2, varscan2
- ERICH3 | c.3688C>G p.P1230A | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100445350; called by muse, mutect2, varscan2
- ERMN | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV101263059; called by muse, mutect2
- ESF1 | c.2289G>T p.Q763H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99176484; called by muse, mutect2, varscan2
- FAAH | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV99680220; called by muse, mutect2, varscan2
- FABP3 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100704112; called by muse, mutect2, varscan2
- FAM135B | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99357956; called by muse, mutect2, varscan2
- FAT3 | c.7456G>C p.V2486L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV99963037, COSV99969674; called by muse, mutect2, varscan2
- FBXO11 | c.808G>A p.D270N (on ENST00000403359 / NM_001190274.2; = p.D186N on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100319861; called by muse, mutect2
- FCAR | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as COSV100629165; called by muse, mutect2, varscan2
- FCRL4 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 98/438 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as COSV99620301; called by muse, mutect2, varscan2
- FCRL5 | c.2928C>G p.H976Q | Missense Mutation (SNP) | VAF 100/383 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV100709252; called by muse, mutect2, varscan2
- FER1L6 | c.2929C>A p.Q977K | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.105); catalogued as COSV101206132; called by muse, mutect2, varscan2
- FFAR1 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.425); catalogued as COSV99323663; called by muse, mutect2
- FGFR3 | c.*1330C>T | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as rs747369218, COSV99603154; called by muse, mutect2, varscan2
- FHL5 | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100459674; called by muse, mutect2, varscan2
- FLII | c.2269G>T p.V757L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs1482613474, COSV100375608; called by muse, mutect2, varscan2
- FLII | c.2268G>T p.K756N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); catalogued as COSV57499506; called by muse, mutect2, varscan2
- FLRT2 | c.972G>C p.W324C | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100420881; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2055del p.G687Afs*8 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as COSV100436583; called by mutect2, pindel, varscan2
- FZD4 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV101536067; called by muse, mutect2, varscan2
- GABRG1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54954998, COSV99778580; called by muse, mutect2, varscan2
- GALT | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as CM095708, COSV101122791; called by muse, mutect2, varscan2
- GIPC2 | c.137C>G p.A46G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99503838; called by muse, mutect2, varscan2
- GRIA4 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.928); catalogued as COSV56894202, COSV56908240; called by muse, mutect2, varscan2
- GSDMD | c.219C>T p.D73= | Splice Region (SNP) | VAF 19/52 reads (37%) | catalogued as rs746252969, COSV99369568; called by muse, mutect2, varscan2
- H1-2 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs749161844, COSV100642322; called by muse, mutect2, varscan2
- HELZ2 | c.6481G>A p.V2161I (on ENST00000467148 / NM_001037335.2; = p.V1592I on NM_033405.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.083); catalogued as COSV101427528, COSV101427600; called by muse, mutect2
- HEPHL1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV100244242; called by muse, mutect2, varscan2
- HFM1 | c.4163_4164insT p.N1390Kfs*6 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | catalogued as COSV99646600; called by mutect2, varscan2
- HIF1A | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100049174; called by muse, mutect2, varscan2
- HIKESHI | c.513C>G p.F171L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99563601; called by muse, mutect2, varscan2
- HIPK1 | c.2789G>T p.R930M | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100479558; called by muse, mutect2, varscan2
- HOXD12 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.565); catalogued as COSV101184225, COSV66832975; called by muse, mutect2, varscan2
- HTR4 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.802); catalogued as COSV100089332, COSV58790998; called by muse, mutect2, varscan2
- IGSF1 | c.3593G>T p.G1198V | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100812261; called by muse, mutect2, varscan2
- IL1R1 | c.391A>T p.K131* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99292846; called by muse, mutect2, varscan2
- IL21 | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV99144477; called by muse, mutect2, varscan2
- IMPDH1 | c.531G>A p.V177= (on ENST00000470772 / NM_001142573.2; = p.V263= on NM_000883.4) | Splice Region (SNP) | VAF 84/188 reads (45%) | catalogued as rs756681486, COSV100118781; called by muse, mutect2, varscan2
- INTU | c.2581G>C p.G861R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100080521, COSV100081257; called by muse, mutect2, varscan2
- ITPR2 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.956); catalogued as COSV99659553; called by muse, mutect2, varscan2
- ITPR3 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1417841516, COSV100967951; called by muse, mutect2, varscan2
- JAG1 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV99653396; called by muse, mutect2
- JAK2 | c.2653C>T p.Q885* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV101078346, COSV67629302; called by muse, mutect2, varscan2
- JAK3 | c.2864T>C p.I955T | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101512997; called by muse, mutect2, varscan2
- KAT2A | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99863668; called by muse, mutect2, varscan2
- KCNA2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100316090; called by muse, mutect2, varscan2
- KCNA6 | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768891; called by muse, mutect2, varscan2
- KCNT2 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99656052; called by muse, mutect2, varscan2
- KDM3B | c.2947G>C p.D983H | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100070135; called by muse, mutect2, varscan2
- KIF11 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99586085; called by muse, mutect2, varscan2
- KLF12 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100888617; called by muse, mutect2, varscan2
- KLF7 | c.673G>T p.G225W | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58746484; called by muse, mutect2, varscan2
- KLRC1 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV100760865; called by muse, mutect2, varscan2
- KMT2D | c.10678G>A p.D3560N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56456697; called by muse, mutect2, varscan2
- LAMA4 | c.2872G>T p.E958* (on ENST00000230538 / NM_001105206.3; = p.E951* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100039174; called by muse, mutect2
- LAMA4 | c.2870A>T p.E957V (on ENST00000230538 / NM_001105206.3; = p.E950V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100039180; called by muse, mutect2
- LASP1 | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100530441; called by muse, mutect2, varscan2
- LEPR | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100756725; called by muse, mutect2, varscan2
- LGR6 | c.855G>T p.T285= (on ENST00000367278 / NM_001017403.1; = p.T233= on NM_021636.3) | Splice Region (SNP) | VAF 24/84 reads (29%) | catalogued as COSV55151967, COSV99707686; called by muse, mutect2, varscan2
- LINGO4 | c.119A>G p.Q40R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs1169308301, COSV100562071; called by muse, mutect2, varscan2
- LMNB2 | c.1562A>G p.Y521C | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV99296084; called by muse, mutect2, varscan2
- LNPEP | c.3077A>T p.*1026Lext*82 | Nonstop Mutation (SNP) | VAF 31/115 reads (27%) | catalogued as COSV99183585; called by muse, mutect2, varscan2
- LRFN5 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99985057; called by mutect2, varscan2
- LRIT3 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.089); catalogued as COSV100016351; called by muse, mutect2, varscan2
- LRP1B | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101259643; called by muse, mutect2
- LRRC66 | c.1850A>T p.Q617L | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.092); catalogued as COSV100603061; called by muse, mutect2, varscan2
- LRRC7 | c.408C>A p.D136E (on ENST00000651989 / NM_001370785.2; = p.D103E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99229060; called by muse, mutect2, varscan2
- LRRTM3 | c.617G>T p.R206I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100791875; called by muse, mutect2, varscan2
- LTBP1 | c.5149G>T p.D1717Y (on ENST00000404816 / NM_206943.4; = p.D1391Y on NM_000627.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV55384937, COSV99698656; called by muse, mutect2, varscan2
- MAST2 | c.2223G>C p.E741D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.042); catalogued as rs1320718000, COSV100788683; called by muse, mutect2, varscan2
- MED8 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV99318484; called by muse, mutect2, varscan2
- METTL22 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs532682905, COSV99371829; called by muse, mutect2, varscan2
- METTL25 | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50257586; called by muse, mutect2, varscan2
- MGAT5B | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs747414462, COSV56928790; called by muse, mutect2, varscan2
- MICU2 | c.1181G>C p.R394T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101212479; called by muse, mutect2, varscan2
- MINAR1 | c.1979C>G p.S660C | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100549151; called by muse, mutect2, varscan2
- MMP16 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99689072; called by mutect2, varscan2
- MNDA | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100933421; called by muse, mutect2, varscan2
- MPO | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99229229; called by muse, mutect2, varscan2
- MUC16 | c.16864A>G p.T5622A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.096); catalogued as rs779890679, COSV101201057; called by muse, mutect2, varscan2
- MYH1 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV99876659; called by muse, mutect2
- MYH11 | c.4182G>C p.K1394N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100259922; called by muse, mutect2, varscan2
- MYH14 | c.1677G>T p.W559C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99223761; called by muse, mutect2, varscan2
- MYH4 | c.3346C>A p.Q1116K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99702007; called by muse, mutect2, varscan2
- MYO18A | c.4157A>T p.K1386M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100572590; called by muse, mutect2, varscan2
- MYO3B | c.1770G>T p.R590S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100511416; called by muse, mutect2, varscan2
- NCAPD2 | c.1673A>T p.E558V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100217384; called by muse, mutect2, varscan2
- NCOA7 | c.989A>C p.K330T | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as COSV99997525; called by muse, mutect2, varscan2
- NDST3 | c.1230C>G p.H410Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as COSV99630190, COSV99631538, COSV99631897; called by muse, mutect2, varscan2
- NEGR1 | c.614C>A p.A205E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100165398, COSV60868612, COSV60871717; called by muse, mutect2, varscan2
- NF1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV62205875; called by muse, mutect2, varscan2
- NF1 | c.6002G>T p.G2001V (on ENST00000358273 / NM_001042492.3; = p.G1980V on NM_000267.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs878853905, COSV100648002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP13 | c.613C>A p.R205S | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.688); catalogued as COSV100738434, COSV61622102; called by muse, mutect2, varscan2
- NLRP3 | c.2124C>A p.S708R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100276506; called by muse, mutect2, varscan2
- NPR3 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs1011584298, COSV54088924; called by muse, mutect2, varscan2
- NR1H4 | c.1217C>A p.S406Y (on ENST00000551379 / NM_001206993.2; = p.S392Y on NM_005123.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV99501040; called by muse, mutect2
- NRAS | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101055869; called by muse, mutect2, varscan2
- NRG3 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100932477; called by muse, mutect2, varscan2
- NSF | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs773404010, COSV56574478; called by muse, mutect2, varscan2
- NTNG2 | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV100647673; called by muse, mutect2, varscan2
- NUCB1 | c.695G>T p.W232L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV99618094; called by muse, mutect2, varscan2
- OBSL1 | c.1951G>T p.G651W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54729917; called by muse, mutect2, varscan2
- OLIG2 | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV100324334; called by muse, mutect2, varscan2
- OR10S1 | c.872C>G p.T291R | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV101602500; called by muse, mutect2, varscan2
- OR10V1 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV100276196; called by muse, mutect2, varscan2
- OR1S2 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100224118, COSV100224342; called by muse, mutect2, varscan2
- OR2T4 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV63543323, COSV63543976, COSV63545316; called by muse, mutect2, varscan2
- OR4C13 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV101634171, COSV101634225; called by muse, mutect2, varscan2
- OR4N2 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as rs148127407, COSV100269902; called by muse, mutect2
- OR4N5 | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1271434490, COSV100374195; called by muse, mutect2, varscan2
- OR4Q3 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100056907, COSV59180246; called by muse, mutect2, varscan2
- OR52M1 | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs756589356, COSV100798609; called by muse, mutect2, varscan2
- OR6K3 | c.125T>C p.L42P (on ENST00000368146; = p.L26P on NM_001005327.2) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100933878; called by muse, mutect2, varscan2
- OR7G3 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV59640539; called by muse, mutect2, varscan2
- OR8J3 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100040984; called by muse, mutect2, varscan2
- OR8K1 | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as COSV54402730, COSV99687494; called by muse, mutect2, varscan2
- OR8U1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV100164076; called by muse, varscan2
- OR9G4 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100265057, COSV100265230; called by muse, mutect2, varscan2
- P2RY10 | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99409313; called by muse, mutect2, varscan2
- PACRG | c.203A>T p.K68M | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV100434746; called by muse, mutect2, varscan2
- PANX1 | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99921981; called by muse, mutect2, varscan2
- PAPPA2 | c.2662G>T p.G888W | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62784109; called by muse, mutect2, varscan2
- PAPPA2 | c.3248C>A p.P1083H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.179); catalogued as COSV100868503; called by muse, mutect2, varscan2
- PAX3 | c.341T>A p.V114E | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99286754; called by muse, mutect2, varscan2
- PCDH9 | c.2998G>T p.G1000* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100122782, COSV60532031; called by muse, mutect2, varscan2
- PCDHA10 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs1554150112, COSV56505571; called by muse, varscan2
- PCDHA11 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100253417; called by muse, mutect2, varscan2
- PCDHB4 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as COSV99522449; called by muse, mutect2, varscan2
- PCDHB6 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as rs782741715, COSV99170756; called by muse, mutect2, varscan2
- PCDHB8 | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV99177260; called by muse, mutect2, varscan2
- PCDHGA2 | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53955545; called by muse, mutect2, varscan2
- PDZRN3 | c.2961G>C p.E987D | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV99731530; called by muse, mutect2, varscan2
- PEG3 | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs764998224, COSV99690066; called by muse, mutect2, varscan2
- PGA3 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.55); catalogued as COSV100337393; called by muse, mutect2, varscan2
- PIK3C2G | c.3005G>T p.G1002V (on ENST00000676171; = p.G961V on NM_004570.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99853500; called by muse, mutect2, varscan2
- PKIB | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99236584; called by muse, mutect2, varscan2
- PLAAT3 | c.393A>T p.R131S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100071879; called by muse, mutect2, varscan2
- PNP | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs922257453, COSV100829005; called by muse, mutect2, varscan2
- POLQ | c.5488G>T p.V1830L | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV51745106, COSV99952730; called by muse, mutect2, varscan2
- POLR3B | c.966A>G p.P322= | Splice Region (SNP) | VAF 11/49 reads (22%) | catalogued as rs764892043, COSV99943785; called by muse, mutect2, varscan2
- PPP1R12B | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs753256240, COSV99295181; called by muse, mutect2, varscan2
- PRCP | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV57290027; called by muse, mutect2, varscan2
- PRKCB | c.223C>A p.H75N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335054; called by muse, mutect2, varscan2
- PROKR2 | c.824T>A p.L275Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV99450563; called by muse, mutect2, varscan2
- PRRC2A | c.1920G>C p.Q640H | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1172952274, COSV101051340, COSV65686185; called by muse, mutect2, varscan2
- PRRC2C | c.1177G>T p.G393W (on ENST00000367742; = p.G391W on NM_015172.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100145115; called by muse, mutect2
- PRX | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); catalogued as rs906147559, COSV99397984; called by muse, mutect2, varscan2
- PTPN21 | c.1367A>T p.K456M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV100162421; called by muse, mutect2, varscan2
- PTPRB | c.3542G>A p.G1181E | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as COSV99718646; called by muse, mutect2, varscan2
- PTPRR | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs760678361, COSV51727862; called by muse, mutect2, varscan2
- PXDNL | c.2683G>T p.D895Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100685663, COSV62500805; called by muse, mutect2, varscan2
- RAD54B | c.1996G>A p.V666I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs774280011, COSV100280121; called by muse, mutect2
- RALGAPA1 | c.2011A>G p.K671E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.72); catalogued as COSV99355789; called by muse, mutect2, varscan2
- RBL1 | c.1408A>G p.K470E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs570797631, COSV100727258; called by mutect2, varscan2
- RBM38 | c.450C>G p.I150M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs569633738, COSV100654889, COSV61135504; called by muse, mutect2, varscan2
- RIBC2 | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 118/432 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100734211, COSV61581077; called by muse, mutect2, varscan2
- RNASE2 | c.402T>A p.Y134* | Nonsense Mutation (SNP) | VAF 38/158 reads (24%) | catalogued as COSV100482092; called by muse, mutect2, varscan2
- RNF17 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV99694141; called by muse, mutect2
- ROCK2 | c.1417G>T p.V473F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV99837763; called by muse, mutect2, varscan2
- RPS24 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100680681; called by muse, mutect2, varscan2
- RRP12 | c.3535G>T p.A1179S | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV100213400; called by muse, mutect2, varscan2
- RUNX3 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100137048; called by muse, mutect2, varscan2
- RYR2 | c.6921C>A p.F2307L | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100767315, COSV100772246; called by muse, mutect2, varscan2
- SAMD9L | c.2912T>C p.L971P | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100561063; called by muse, mutect2, varscan2
- SCARF2 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV99839422; called by muse, varscan2
- SCN11A | c.3515T>A p.I1172K | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100182221; called by muse, mutect2, varscan2
- SCN5A | c.4573G>T p.V1525L (on ENST00000333535 / NM_198056.3; = p.V1524L on NM_000335.5) | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as CM100737, COSV100350111; called by muse, mutect2, varscan2
- SCYL3 | c.104A>T p.K35I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100884314; called by muse, mutect2, varscan2
- SENP7 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100053750; called by muse, mutect2, varscan2
- SERPINC1 | c.673A>T p.K225* | Nonsense Mutation (SNP) | VAF 7/157 reads (4%) | catalogued as COSV100875111; called by muse, mutect2
- SHANK1 | c.3424C>A p.P1142T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV99521823; called by muse, mutect2, varscan2
- SI | c.3732C>G p.D1244E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100013989, COSV52282786; called by muse, mutect2, varscan2
- SLC12A9 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 93/146 reads (64%) | SIFT tolerated (0.63); PolyPhen benign (0.328); catalogued as COSV99308111; called by muse, mutect2, varscan2
- SLC16A4 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63915937; called by muse, mutect2, varscan2
- SLC17A2 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99614847; called by muse, mutect2, varscan2
- SLC2A13 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV55111779, COSV99786957; called by muse, mutect2, varscan2
- SLC2A14 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV100533969; called by muse, mutect2, varscan2
- SLC7A13 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.134); catalogued as rs779516708, COSV99879133; called by muse, mutect2, varscan2
- SLC7A13 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99879137; called by muse, mutect2, varscan2
- SLC7A14 | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99200837; called by muse, mutect2
- SLC8A1 | c.1361G>C p.G454A | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs961417845, COSV100247151; called by muse, mutect2, varscan2
- SLIT3 | c.4054G>T p.V1352L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as COSV100269323; called by muse, mutect2, varscan2
- SLITRK3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99579890; called by muse, mutect2, varscan2
- SMAD4 | c.1474G>T p.V492F | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61686351; called by muse, mutect2, varscan2
- SMARCA5 | c.1726T>A p.L576M | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV99304100; called by muse, mutect2, varscan2
- SON | c.5588C>G p.S1863* | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | catalogued as COSV99279477; called by muse, mutect2, varscan2
- SORL1 | c.2064C>A p.F688L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99495121; called by muse, mutect2, varscan2
- SOS1 | c.2489A>G p.N830S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs397517158, COSV67678385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPG7 | c.2039G>T p.G680V (on ENST00000268704; = p.G687V on NM_003119.4) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as COSV99245336; called by muse, mutect2, varscan2
- SPTA1 | c.191A>T p.D64V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100935417; called by muse, mutect2, varscan2
- SRFBP1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.769); catalogued as COSV100232903; called by muse, mutect2, varscan2
- SRP54 | c.1422G>C p.M474I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99392781; called by muse, mutect2, varscan2
- STAC | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56208394, COSV99830589; called by muse, mutect2, varscan2
- STX19 | c.692A>T p.D231V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100115748; called by muse, mutect2, varscan2
- SYNJ2 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184799681, COSV100840592; called by muse, mutect2, varscan2
- SYT16 | c.1474A>C p.S492R | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV101413675; called by muse, mutect2, varscan2
- SYT6 | c.1313C>G p.P438R (on ENST00000610222 / NM_001366225.1; = p.P353R on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV101059699, COSV65774990; called by muse, mutect2, varscan2
- TAAR8 | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99257311; called by muse, mutect2, varscan2
- TAS2R14 | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV101115408; called by muse, mutect2, varscan2
- TEKT4 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as COSV99726644; called by muse, mutect2, varscan2
- TENM3 | c.6097G>T p.V2033L | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV101305396; called by muse, mutect2, varscan2
- TGM6 | c.2005C>A p.Q669K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52479318, COSV99172393; called by muse, mutect2, varscan2
- TIMD4 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV99192643, COSV99192840; called by muse, mutect2, varscan2
- TMEM132D | c.2392G>A p.G798S | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV101243036; called by muse, mutect2
- TMEM174 | c.209G>A p.W70* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV57113141; called by muse, mutect2, varscan2
- TMEM176B | c.720G>T p.L240= | Splice Region (SNP) | VAF 56/86 reads (65%) | catalogued as COSV100423660; called by muse, mutect2, varscan2
- TMIGD2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV100010468; called by muse, mutect2, varscan2
- TMPRSS11F | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100678740; called by muse, mutect2, varscan2
- TNN | c.1489G>C p.V497L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV99512739; called by muse, mutect2, varscan2
- TOM1 | c.1420G>T p.G474C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV101147036; called by muse, mutect2, varscan2
- TRHDE | c.3014G>C p.R1005P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99672037; called by muse, mutect2, varscan2
- TRIM33 | c.2311G>T p.D771Y | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100635655; called by muse, mutect2, varscan2
- TRPM2 | c.2400C>A p.H800Q | Missense Mutation (SNP) | VAF 68/456 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV100309211; called by muse, mutect2, varscan2
- TRPV4 | c.2456G>T p.R819M | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV99924986; called by muse, mutect2, varscan2
- TTN | c.81439T>G p.W27147G (on ENST00000591111; = p.W19723G on NM_003319.4) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | PolyPhen probably damaging (0.997); catalogued as COSV100625757, COSV60410998; called by muse, mutect2, varscan2
- TTN | c.32723T>C p.V10908A (on ENST00000591111; = p.V9981A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | PolyPhen benign (0.001); catalogued as COSV100625762; called by muse, mutect2, varscan2
- UBR4 | c.6484_6486del p.P2162del | In Frame Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs757795486; called by mutect2, pindel, varscan2
- UNC5D | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99776733, COSV99777988; called by muse, mutect2, varscan2
- UNC79 | c.4565G>T p.C1522F (on ENST00000393151 / NM_001346218.2; = p.C1345F on NM_020818.5) | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1486660548, COSV99829500; called by muse, mutect2, varscan2
- URI1 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV100368892; called by muse, mutect2
- USH2A | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100240601; called by muse, mutect2, varscan2
- USP15 | c.1612G>T p.E538* (on ENST00000280377 / NM_001351159.2; = p.E509* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV99740397; called by muse, mutect2, varscan2
- VHLL | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV100372688; called by muse, mutect2, varscan2
- VWA5A | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100795723; called by muse, mutect2, varscan2
- WASHC2A | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as rs1417118300; called by muse, mutect2, varscan2
- WIZ | c.5375C>G p.T1792S (on ENST00000673675 / NM_001371589.1; = p.T697S on NM_021241.3) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV99653656; called by muse, mutect2, varscan2
- XIRP2 | c.444+2T>A p.X148_splice (on ENST00000628543; = p.X323_splice on NM_152381.6) | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99746392; called by muse, mutect2, varscan2
- XKR3 | c.723G>C p.W241C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV58885834; called by mutect2, varscan2
- XPO7 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs1563331676; called by muse, mutect2
- YEATS2 | c.1767G>A p.V589= | Splice Region (SNP) | VAF 17/152 reads (11%) | catalogued as COSV100528208; called by muse, mutect2, varscan2
- YME1L1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58759351; called by muse, mutect2, varscan2
- ZC4H2 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.92); catalogued as COSV100565127, COSV62006654; called by muse, mutect2, varscan2
- ZMAT1 | c.841G>C p.A281P | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767498025, COSV100858779, COSV100858902, COSV65658949; called by muse, mutect2, varscan2
- ZNF17 | c.995G>A p.C332Y | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100300153; called by muse, mutect2, varscan2
- ZNF214 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs766888564, COSV53482598; called by muse, mutect2, varscan2
- ZNF479 | c.1332A>T p.K444N | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs1554399885, COSV100482992; called by muse, mutect2, varscan2
- ZNF479 | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs779577385, COSV100482993; called by muse, mutect2, varscan2
- ZNF536 | c.1125C>A p.C375* | Nonsense Mutation (SNP) | VAF 85/238 reads (36%) | catalogued as COSV100835690; called by muse, mutect2, varscan2
- ZNF69 | c.190+1G>T p.X64_splice (on ENST00000429654 / NM_001364730.1; = p.X50_splice on NM_021915.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100421079; called by muse, mutect2, varscan2
- ZNF99 | c.1274G>A p.C425Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774532388, COSV68055785; called by muse, mutect2, varscan2
- ZP4 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100850655, COSV100850753; called by muse, mutect2, varscan2
- ZSCAN4 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99990264; called by muse, mutect2, varscan2
- ZYG11B | c.2042A>G p.N681S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV99597734; called by muse, mutect2, varscan2
- ABHD8 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2
- CDH16 | c.1273_1274del p.A425Rfs*9 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by pindel, varscan2
- CDK12 | c.836dup p.Y279* | Nonsense Mutation (INS) | VAF 24/133 reads (18%) | called by mutect2, pindel, varscan2
- CEACAM4 | c.163del p.A55Pfs*29 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | called by mutect2, pindel, varscan2
- ERAP1 | c.2567dup p.N856Kfs*10 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- FAT2 | c.10609_10613dup p.T3539Sfs*28 | Frame Shift Ins (INS) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- GLIS1 | c.424del p.A142Rfs*4 | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | called by mutect2, pindel, varscan2
- IGHM | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- IGLV4-3 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- OR5A2 | c.933dup p.I312Dfs*21 | Frame Shift Ins (INS) | VAF 29/134 reads (22%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHETA2 | c.352del p.R118Gfs*93 | Frame Shift Del (DEL) | VAF 38/151 reads (25%) | called by mutect2, pindel, varscan2
- POLR2A | c.3725A>G p.D1242G | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- PRAG1 | c.364del p.L122Sfs*59 | Frame Shift Del (DEL) | VAF 45/130 reads (35%) | called by mutect2, pindel, varscan2
- PTPRB | c.3975del p.R1326Dfs*26 | Frame Shift Del (DEL) | VAF 50/228 reads (22%) | called by mutect2, pindel, varscan2
- RSPH10B | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- RUNX1T1 | c.163dup p.T55Nfs*24 (on ENST00000265814 / NM_001198628.1; = p.T28Nfs*24 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.299C>A p.A100E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- TRAV1-2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.14960G>T p.S4987I (on ENST00000591111; = p.S4060I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | PolyPhen possibly damaging (0.748); called by muse, mutect2
- XKR3 | c.722G>T p.W241L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- ZNF165 | c.406dup p.L136Pfs*7 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | called by mutect2, pindel*, varscan2
- ZNF229 | c.2148dup p.C717Mfs*13 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- ZNF479 | c.1478del p.Y493Sfs*21 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- ZNF600 | c.553T>G p.L185V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABI3BP | c.183G>T p.L61= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV99428240; called by muse, mutect2, varscan2
- ACTL8 | c.54C>A p.G18= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100958770; called by muse, mutect2, varscan2
- ADAMTS16 | c.2982C>T p.P994= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1399783054, COSV99942488; called by muse, mutect2, varscan2
- ADGRG1 | c.1509C>T p.L503= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs369114425; called by muse, mutect2, varscan2
- ADGRL3 | c.1542C>A p.T514= (on ENST00000506720 / NM_001322402.2; = p.T446= on NM_015236.6) | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV101547353; called by muse, mutect2, varscan2
- ADRB3 | c.48C>T p.D16= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs367948517; called by muse, varscan2
- ADTRP | c.36T>C p.L12= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV99995438; called by muse, mutect2, varscan2
- ATP1B4 | c.480C>A p.A160= (on ENST00000218008 / NM_001142447.3; = p.A156= on NM_012069.5) | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV99486482; called by muse, mutect2, varscan2
- AWAT2 | c.630C>T p.R210= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1470516023, COSV99339748; called by muse, mutect2
- BCAS3 | c.2550C>A p.S850= (on ENST00000390652 / NM_001353144.2; = p.S835= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as COSV101176794; called by muse, mutect2, varscan2
- BTN1A1 | c.1047C>G p.G349= | Silent (SNP) | VAF 24/186 reads (13%) | catalogued as COSV55067635, COSV99764518; called by muse, mutect2, varscan2
- CDH10 | c.1815C>A p.L605= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100052728; called by muse, mutect2, varscan2
- CELSR1 | c.6225G>A p.A2075= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs546943922, COSV99419647; called by muse, mutect2, varscan2
- CENPH | c.348G>A p.L116= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99295617; called by muse, mutect2, varscan2
- COL11A1 | c.1005A>G p.E335= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100617850; called by muse, mutect2, varscan2
- COL20A1 | c.2100C>A p.G700= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100491246; called by muse, mutect2, varscan2
- CORO1C | c.513T>C p.D171= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs755025882, COSV99776168; called by muse, mutect2, varscan2
- CPS1 | c.951G>T p.G317= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99243843; called by muse, mutect2, varscan2
- CRNKL1 | c.336G>C p.A112= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs867115962, COSV55636261, COSV99846278, COSV99846944; called by muse, mutect2, varscan2
- CTNND1 | c.2514A>G p.P838= (on ENST00000399050 / NM_001085458.2; = p.P832= on NM_001331.3) | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100650234; called by muse, mutect2, varscan2
- DCST2 | c.1219C>T p.L407= | Silent (SNP) | VAF 47/197 reads (24%) | catalogued as COSV55051098; called by muse, mutect2, varscan2
- DGKA | c.1218G>C p.V406= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as COSV100093332; called by muse, mutect2, varscan2
- DMD | c.2595A>G p.A865= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100822039; called by muse, mutect2, varscan2
- DNAH10 | c.3456G>T p.L1152= (on ENST00000409039; = p.L1091= on NM_207437.3) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101292508; called by muse, mutect2, varscan2
- DPP4 | c.360C>T p.Y120= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs141276765, COSV62106666; called by muse, mutect2, varscan2
- DVL1 | c.1008C>T p.A336= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs371616558; called by muse, mutect2, varscan2
- DYNC2LI1 | c.972G>A p.E324= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV99571497; called by muse, mutect2, varscan2
- EBF3 | c.1275G>T p.L425= (on ENST00000355311 / NM_001375392.1; = p.L416= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/205 reads (43%) | catalogued as COSV100799546; called by muse, mutect2, varscan2
- EEF2K | c.2002C>T p.L668= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99533565; called by muse, mutect2, varscan2
- EPHB1 | c.63G>T p.T21= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV101214067, COSV67667614; called by muse, mutect2, varscan2
- ERICH5 | c.411G>A p.G137= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV100582856; called by muse, mutect2, varscan2
- FA2H | c.906G>T p.A302= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99547528; called by mutect2, varscan2
- FAM47B | c.1444C>T p.L482= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV100264548; called by muse, mutect2, varscan2
- FCRL4 | c.714A>G p.S238= | Silent (SNP) | VAF 97/438 reads (22%) | catalogued as COSV99620296; called by muse, mutect2, varscan2
- FMO1 | c.1347G>T p.L449= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100707892; called by muse, mutect2, varscan2
- FPR1 | c.1026T>A p.S342= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as rs748291297, COSV100494134; called by muse, mutect2
- GRID1 | c.1896C>T p.I632= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs773408585, COSV60052417; called by muse, mutect2, varscan2
- GSDMA | c.1200G>A p.T400= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs369154670; called by muse, mutect2, varscan2
- HDAC5 | c.1251C>T p.F417= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs1214327270, COSV99870913; called by muse, mutect2, varscan2
- HECW1 | c.1632G>T p.T544= | Silent (SNP) | VAF 72/127 reads (57%) | catalogued as rs768142577, COSV101224174, COSV67830395; called by muse, varscan2
- HMCN1 | c.15693G>T p.V5231= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99634220; called by muse, mutect2, varscan2
- IFT80 | c.1098A>C p.P366= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100425061; called by muse, mutect2, varscan2
- IGSF11 | c.489G>C p.L163= (on ENST00000393775 / NM_001015887.3; = p.L162= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100677743; called by muse, mutect2, varscan2
- IL17RD | c.1110C>T p.H370= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs766403704, COSV99577939; called by muse, mutect2, varscan2
- IQGAP2 | c.1845T>C p.T615= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs373417790; called by muse, mutect2, varscan2
- LAMA4 | c.5271C>A p.P1757= (on ENST00000230538 / NM_001105206.3; = p.P1750= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100037545; called by muse, mutect2
- LAT | c.345G>T p.A115= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV100209244; called by muse, mutect2, varscan2
- LILRA6 | c.384C>A p.A128= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- LRBA | c.5715G>A p.R1905= | Silent (SNP) | VAF 70/185 reads (38%) | catalogued as COSV63950516; called by muse, mutect2, varscan2
- MTERF3 | c.492G>C p.V164= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99750005; called by muse, mutect2
- MUC16 | c.33375C>A p.T11125= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV101201054; called by muse, mutect2, varscan2
- MUC16 | c.18624G>A p.L6208= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV101201055; called by muse, mutect2, varscan2
- MYH15 | c.4539G>A p.E1513= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV99844085; called by muse, mutect2, varscan2
- MYO7B | c.5397C>A p.I1799= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV67353753; called by muse, mutect2, varscan2
- NLRP2 | c.1005C>T p.T335= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs193065675; called by muse, mutect2, varscan2
- OGDH | c.2118C>G p.L706= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV99759472; called by muse, mutect2
- OR10G7 | c.594C>A p.I198= | Silent (SNP) | VAF 77/256 reads (30%) | catalogued as COSV57867512; called by muse, mutect2, varscan2
- OR2B11 | c.342G>T p.T114= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV100276508, COSV59511140; called by muse, mutect2, varscan2
- OR4K1 | c.87C>A p.A29= | Silent (SNP) | VAF 59/527 reads (11%) | catalogued as COSV99579230; called by muse, mutect2, varscan2
- OR4N2 | c.162G>T p.G54= | Silent (SNP) | VAF 88/667 reads (13%) | catalogued as rs769462178; called by muse, mutect2, varscan2
- OR4S2 | c.78T>C p.F26= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100412754, COSV56746441; called by muse, mutect2, varscan2
- OR8B2 | c.276C>T p.I92= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs1216226307, COSV100899476; called by muse, mutect2, varscan2
- PCDH11X | c.1500G>A p.K500= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1265091785, COSV100010692; called by muse, mutect2, varscan2
- PCDHA12 | c.1350C>T p.D450= | Silent (SNP) | VAF 75/239 reads (31%) | catalogued as COSV100253418; called by muse, mutect2, varscan2
- PCDHB6 | c.1959C>T p.T653= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as rs200771171, COSV99170762; called by muse, mutect2, varscan2
- PI4KB | c.570G>T p.V190= (on ENST00000368873 / NM_001369623.1; = p.V202= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV99650060; called by muse, mutect2, varscan2
- POSTN | c.891C>G p.S297= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV101123459, COSV65712171; called by muse, mutect2, varscan2
- PRKAA2 | c.420G>C p.L140= | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as COSV100983030, COSV64803046; called by muse, mutect2, varscan2
- PRRC1 | c.321A>T p.V107= | Silent (SNP) | VAF 84/201 reads (42%) | catalogued as COSV99688089; called by muse, mutect2, varscan2
- PTPRN | c.1470G>A p.L490= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs1041185715, COSV55346717; called by muse, mutect2, varscan2
- PYHIN1 | c.321G>A p.T107= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100932398; called by muse, mutect2, varscan2
- RASAL1 | c.1710C>A p.G570= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as COSV99922037; called by muse, mutect2, varscan2
- RBAK | c.969G>T p.G323= | Silent (SNP) | VAF 83/137 reads (61%) | catalogued as COSV100806739; called by muse, mutect2, varscan2
- RNASE10 | c.285G>A p.K95= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100116205; called by muse, mutect2, varscan2
- RNF113B | c.354C>T p.T118= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs376046437, COSV57436344; called by muse, varscan2
- RNF113B | c.291C>A p.T97= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99940409; called by muse, varscan2
- RNF20 | c.675C>T p.L225= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs763268347, COSV100874335; called by muse, mutect2, varscan2
- SLC17A8 | c.303G>T p.V101= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV100035760; called by muse, mutect2, varscan2
- SLC26A5 | c.1536A>G p.G512= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV100099951; called by muse, mutect2, varscan2
- SMAD3 | c.258C>G p.V86= | Silent (SNP) | VAF 82/217 reads (38%) | catalogued as COSV100529394; called by muse, mutect2, varscan2
- SPSB3 | c.915C>T p.L305= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as COSV99457351; called by muse, mutect2, varscan2
- STON2 | c.1998A>G p.A666= (on ENST00000649389 / NM_001366849.2; = p.A609= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs754426063, COSV99965092; called by muse, mutect2, varscan2
- TAF1L | c.42C>A p.T14= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV54263593, COSV99645184; called by muse, mutect2, varscan2
- TAS2R9 | c.642G>T p.L214= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV99553930; called by muse, mutect2, varscan2
- TBC1D23 | c.1452A>G p.K484= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100792724; called by muse, mutect2, varscan2
- TBXT | c.1155C>A p.P385= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs904844614, COSV51616111, COSV99752838; called by muse, mutect2, varscan2
- TBXT | c.576C>T p.F192= | Silent (SNP) | VAF 100/316 reads (32%) | catalogued as COSV99752841; called by muse, mutect2, varscan2
- THG1L | c.882A>G p.L294= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs775344139, COSV99180283; called by muse, mutect2, varscan2
- TLN2 | c.1734T>C p.C578= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100169845; called by muse, mutect2, varscan2
- TLR10 | c.1437T>A p.T479= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100457961; called by muse, mutect2, varscan2
- TTN | c.84231A>G p.P28077= (on ENST00000591111; = p.P20653= on NM_003319.4) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100625756; called by mutect2, varscan2
- UBR4 | c.13167G>A p.K4389= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV100921530; called by muse, mutect2, varscan2
- UBXN4 | c.1180T>C p.L394= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV99739517; called by muse, mutect2, varscan2
- VWA5A | c.1389G>A p.Q463= | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as COSV100827803, COSV100827943; called by muse, mutect2, varscan2
- ZBED1 | c.669C>T p.P223= | Silent (SNP) | VAF 76/193 reads (39%) | catalogued as COSV100585979; called by muse, mutect2, varscan2
- ZDBF2 | c.3618T>C p.P1206= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100985376; called by muse, mutect2, varscan2
- ZEB2 | c.1737T>C p.T579= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV100356664; called by muse, mutect2, varscan2
- ZIC1 | c.546C>A p.T182= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV99292284; called by muse, mutect2, varscan2
- ZNF438 | c.144C>A p.S48= | Silent (SNP) | VAF 46/181 reads (25%) | catalogued as COSV100062521, COSV59195563; called by muse, mutect2, varscan2
- ZNF614 | c.855A>G p.K285= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs747482172, COSV99571933; called by muse, mutect2, varscan2
- ZNF676 | c.1104C>A p.P368= (on ENST00000650058; = p.P336= on NM_001001411.3) | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV68094964; called by muse, mutect2
- AC092718.9 | chr16:81154091 G>A | 3'Flank (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849337 T>G | 5'Flank (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- C2orf83 | n.435C>A | RNA (SNP) | VAF 31/118 reads (26%) | catalogued as COSV100018206; called by muse, mutect2, varscan2
- CAPZB | c.*51C>G | 3'UTR (SNP) | VAF 36/196 reads (18%) | catalogued as COSV99940215; called by muse, mutect2, varscan2
- DST | c.4297-1118A>T | Intron (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99759064; called by muse, mutect2, varscan2
- GCNT2 | c.926-35254G>C | Intron (SNP) | VAF 33/169 reads (20%) | catalogued as rs757865819, COSV99399500; called by muse, mutect2, varscan2
- HERC2P3 | n.151G>C | RNA (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44570532 C>T | 3'Flank (SNP) | VAF 11/42 reads (26%) | catalogued as rs192156267; called by muse, mutect2, varscan2
- MIR512-1 | n.69G>T | RNA (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49595004 G>C | 5'Flank (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99882535; called by muse, mutect2
- SYTL2 | c.1460-3216C>T | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as rs1461729091, COSV100314743; called by muse, mutect2, varscan2
